Gene-level copy-number profile of tumor specimen HTMCP-01-20-00272-01A from CGCI case HTMCP-01-20-00272, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 47.8 years (17,461 days).
Specimen HTMCP-01-20-00272-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68924163-6e04-4420-9ad9-3e2c99abe741.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-20-00272-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/a074bb57-ea9f-46ca-b8a4-0573141b9402

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 3,168; copy number 2: 54,587; copy number 3: 977; copy number 4: 51; copy number 5: 4; copy number 6: 21; copy number 8: 1; copy number 9: 1; copy number 11: 1; copy number 13: 1; copy number 16: 1; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,422,555–28,422,655, 1 gene (within-gene range 0–2): Y_RNA.
- chr2:88,857,161–89,245,596, 38 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr7:65,141,032–65,234,216, 1 gene (within-gene range 0–2): INTS4P1.
- chr9:66,721,158–66,745,929, 3 genes: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr14:105,620,506–105,673,314, 7 genes (within-gene range 0–1): IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–1): IGHEP1.
- chr14:105,785,505–105,845,678, 2 genes (within-gene range 0–1): ATP6V1G1P1, IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–1): MIR4539.
- chr14:105,858,165–105,932,642, 40 genes (within-gene range 0–1): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1.
- chr19:39,196,964–39,204,263, 2 genes: NCCRP1, SYCN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,533,681–62,662,829, 1 gene, copy number 8 (within-gene range 3–8): AC092155.1.
- chr3:93,843,764–93,843,862, 1 gene, copy number 5: RNU6-488P.
- chr7:76,531,319–76,541,459, 1 gene, copy number 11 (within-gene range 2–11): SPDYE16.
- chr9:40,883,634–40,883,763, 1 gene, copy number 9: AL353626.2.
- chr9:64,810,865–64,811,429, 1 gene, copy number 6: BNIP3P4.
- chr10:95,141,925–95,168,425, 1 gene, copy number 16: AL157834.4.
- chr11:48,526,064–48,908,946, 9 genes, copy number 6: OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:63,369,785–63,410,294, 1 gene, copy number 5: SLC22A9.
- chr14:24,036,453–24,051,028, 1 gene, copy number 5: DHRS4L1.
- chr15:21,980,277–22,095,857, 6 genes, copy number 6–13 (within-gene range 3–23): OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,095,472, 2 genes, copy number 6 (within-gene range 3–23): OR4M2, OR4N4.
- chr15:32,398,956–32,461,809, 6 genes, copy number 6–19 (within-gene range 1–19): AC135983.1, ULK4P1, U8, DNM1P32, RN7SL539P, AC135983.5.
- chr19:53,793,741–53,824,394, 1 gene, copy number 5: NLRP12.

Autosomal genes at a single copy (total copy number 1): 504. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
